MMRF case MMRF_1674 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/41245fe3-fb04-464b-9daa-48bec52665ac

Demographics
Sex at birth: female; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.0 years (25,579 days); ISS stage: II; Days to last known disease status: 1,184 days (3.2 years); Days to last follow up: 1,184 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 104 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 63 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 64 days; Days to treatment end: 104 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 138 days; Days to treatment end: 138 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 140 days; Days to treatment end: 140 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 235 days; Days to treatment end: 912 days (2.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 1 (ECOG 1): M Protein 7.58 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 13.1 mg/dL; Immunoglobulin G 2.47 g/L; Immunoglobulin A 88.4 g/L; Immunoglobulin M 0.04 g/L; Beta 2 Microglobulin 3.61 µg/mL; Lactate Dehydrogenase 1.87 µkat/L; Hemoglobin 4.4 mmol/L; Leukocytes 3.3 ×10⁹/L; Absolute Neutrophil 0.8 ×10⁹/L; Platelets 76 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.15 mmol/L; Albumin 22 g/L; Total Protein 11.3 g/dL; Glucose 5.01 mmol/L; C-Reactive Protein 0.207 mg/dL.
- Day 85 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.58 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.5 mg/dL; Immunoglobulin G 4.75 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 1.39 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 8.7 ×10⁹/L; Absolute Neutrophil 5.74 ×10⁹/L; Platelets 269 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.05 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 6.05 mmol/L.
- Day 168 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.83 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.89 mg/dL; Immunoglobulin G 7.99 g/L; Immunoglobulin A 0.56 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 2.83 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 44.2 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.18 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 5.89 mmol/L.
- Day 281 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.64 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.68 mg/dL; Immunoglobulin G 8.59 g/L; Immunoglobulin A 1 g/L; Immunoglobulin M 0.35 g/L; Beta 2 Microglobulin 1.11 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 2.85 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.1 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 5.78 mmol/L.
- Day 365 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.87 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 10.8 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.32 g/L; Beta 2 Microglobulin 1.62 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 5.5 ×10⁹/L; Absolute Neutrophil 3.25 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 45.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 7 g/dL; Glucose 4.46 mmol/L.
- Day 470 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.32 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.96 mg/dL; Immunoglobulin G 10.9 g/L; Immunoglobulin A 1.51 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 1.56 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.05 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 6.16 mmol/L.
- Day 526 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 1.72 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 1.69 µg/mL; Lactate Dehydrogenase 2.97 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.15 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 54.8 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 5.39 mmol/L.
- Day 610 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.95 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.83 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 1.68 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 2.04 µg/mL; Lactate Dehydrogenase 2.75 µkat/L; Hemoglobin 6.14 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 5.47 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 35 g/L; Total Protein 6.9 g/dL; Glucose 5.56 mmol/L.
- Day 729 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.55 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 12 g/L; Immunoglobulin A 1.84 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 1.25 µg/mL; Lactate Dehydrogenase 2.8 µkat/L; Hemoglobin 6.32 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.07 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 46.9 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.23 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 5.45 mmol/L.
- Day 841 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.15 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 12.4 g/L; Immunoglobulin A 2.07 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.79 ×10⁹/L; Platelets 210 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 7.5 g/dL; Glucose 4.35 mmol/L.
- Day 897 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.93 mg/dL; Immunoglobulin G 12.1 g/L; Immunoglobulin A 1.97 g/L; Immunoglobulin M 0.3 g/L; Beta 2 Microglobulin 1.59 µg/mL; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.06 ×10⁹/L; Platelets 213 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7.2 g/dL; Glucose 6.16 mmol/L.
- Day 981 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.16 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.72 mg/dL; Immunoglobulin G 13.1 g/L; Immunoglobulin A 2.31 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 1.38 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 3.16 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.2 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 5.17 mmol/L.
- Day 1,079 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.83 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 3.38 g/L; Immunoglobulin M 0.27 g/L; Beta 2 Microglobulin 1.35 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 5.38 ×10⁹/L; Platelets 252 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.08 mmol/L; Albumin 38 g/L; Total Protein 6.8 g/dL; Glucose 5.34 mmol/L.
- Day 1,184 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.61 mg/dL; Immunoglobulin G 12.7 g/L; Immunoglobulin A 2.99 g/L; Immunoglobulin M 0.29 g/L; Beta 2 Microglobulin 1.84 µg/mL; Lactate Dehydrogenase 2.82 µkat/L; Hemoglobin 6.82 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.07 ×10⁹/L; Platelets 236 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 7.6 g/dL; Glucose 5.61 mmol/L.

Other clinical attributes
- Day 1: Weight: 58 kg; Height: 165 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1674_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 1 day.
- Sample MMRF_1674_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 1 day.
